Somatic mutation profile of tumor specimen TCGA-HC-A8D0-01A (aliquot TCGA-HC-A8D0-01A-11D-A364-08) from TCGA case TCGA-HC-A8D0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.5 years (22,465 days).
Specimen TCGA-HC-A8D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d25527b-34de-4c9f-a000-8af1662f020e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A8D0-10A (Blood Derived Normal), aliquot TCGA-HC-A8D0-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9fbadda-7079-44c4-9798-77b887270b13

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP17A | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs1174387666, COSV100002158; called by muse, mutect2, varscan2
- APC | c.4658C>T p.A1553V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1554086050, COSV99967364, COSV99970347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTNL8 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs200621852, COSV99180611; called by muse, mutect2, varscan2
- CAND2 | c.2032G>A p.A678T (on ENST00000456430 / NM_001162499.2; = p.A585T on NM_012298.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.042); catalogued as rs779143752, COSV99928971; called by muse, mutect2, varscan2
- CNTNAP2 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV100665546; called by muse, mutect2, varscan2
- HAUS7 | c.720C>G p.H240Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100444079, COSV57850083; called by muse, mutect2, varscan2
- ITIH4 | c.1415A>G p.N472S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs755577420, COSV99819256; called by muse, mutect2, varscan2
- KCNH7 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs1206533551, COSV100035447; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2413C>T p.L805F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs1380300813, COSV100186722; called by muse, mutect2, varscan2
- NOMO1 | c.2707C>G p.R903G | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55057659, COSV99814442; called by muse, mutect2, varscan2
- PCDHA12 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56479342; called by muse, mutect2, varscan2
- PCDHB12 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs1297969778, COSV53395290; called by muse, mutect2, varscan2
- PEX5L | c.1092G>T p.Q364H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV99828467; called by muse, mutect2, varscan2
- PHF23 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.078); catalogued as COSV99138463; called by muse, mutect2
- TMPRSS2 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100151607; called by muse, mutect2
- ZNF276 | c.631_636del p.G211_A212del (on ENST00000443381 / NM_001113525.2; = p.G136_A137del on NM_152287.4) | In Frame Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ADCK2 | c.193C>T p.L65= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1264046666, COSV99301567; called by muse, mutect2, varscan2
- IGSF3 | c.1113C>T p.S371= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs370839007; called by muse, mutect2, varscan2
- KCNH7 | c.1890C>T p.F630= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100033700; called by muse, mutect2, varscan2
- MTTP | c.2529G>A p.K843= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99645046; called by muse, mutect2, varscan2
- PPP1R3A | c.2136A>G p.E712= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV99492663; called by muse, mutect2, varscan2
- STK33 | c.1164G>A p.S388= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs779391532, COSV59397715; called by muse, mutect2
